CPTAC case C3N-04687 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f28fa0c-b5b1-4cd9-8320-e99e1e5e59c6

Demographics
Sex at birth: male; Race: white; Year of birth: 1956; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 62.5 years (22,816 days); Year of diagnosis: 2018; Days to last known disease status: 0 days; Days to last follow up: 0 days.
   Pathology details: Greatest tumor dimension: 5 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Other clinical attributes
- Weight: 83 kg; Height: 178 cm; BMI: 26.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 7; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 1985; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 7.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04687-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 542 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04687-22: Section location: Frontal Lobe; Percent tumor nuclei: 50; Percent necrosis: 35.
- Sample C3N-04687-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
